Somatic mutation profile of tumor specimen TCGA-FX-A76Y-01A (aliquot TCGA-FX-A76Y-01A-11D-A351-09) from TCGA case TCGA-FX-A76Y, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 49.8 years (18,181 days).
Specimen TCGA-FX-A76Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0050d879-493e-44ba-87e0-885c5fdc3c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FX-A76Y-10A (Blood Derived Normal), aliquot TCGA-FX-A76Y-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfd27d93-b697-46dd-a11e-6186a6463e8c

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1435580496, COSV99288789; called by muse, mutect2, varscan2
- AQP6 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100210184; called by muse, mutect2
- ARAP2 | c.5109G>T p.L1703F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100394808; called by muse, mutect2, varscan2
- DNAH10 | c.3515C>A p.T1172K (on ENST00000409039; = p.T1111K on NM_207437.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV101292339; called by muse, mutect2, varscan2
- ELOA | c.1773A>G p.S591= | Splice Region (SNP) | VAF 17/50 reads (34%) | catalogued as COSV101403756; called by muse, mutect2, varscan2
- FMOD | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461962857, COSV100724563; called by muse, mutect2, varscan2
- MAP1B | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.981); catalogued as COSV99702543; called by muse, mutect2, varscan2
- NAPRT | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV99435004; called by muse, varscan2
- NCKAP5 | c.2062G>T p.V688F | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV100492695; called by muse, mutect2, varscan2
- PCLO | c.6773G>T p.S2258I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100433774; called by muse, mutect2, varscan2
- PPIAL4G | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101344012; called by muse, mutect2, varscan2
- PRKACA | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100432098; called by muse, mutect2, varscan2
- RBM15 | c.1161G>C p.E387D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as COSV100873457; called by muse, mutect2, varscan2
- RNF149 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99766651; called by muse, varscan2
- RPS5 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs1263817648, COSV99544972; called by muse, mutect2
- SACS | c.11089C>G p.L3697V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV101207508; called by muse, mutect2, varscan2
- SOX5 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100507195, COSV58619338; called by mutect2, varscan2
- ZNF414 | c.155C>A p.T52K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV99726642; called by muse, mutect2
- PHACTR1 | c.602del p.P201Qfs*27 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- HERC6 | c.1605C>T p.I535= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99986752; called by muse, mutect2, varscan2
- HTR5A | c.420C>T p.Y140= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV99839783; called by muse, mutect2, varscan2
- LAMA1 | c.519C>A p.T173= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs1483075851, COSV101056688; called by muse, mutect2, varscan2
